Somatic mutation profile of tumor specimen MMRF_2581_1_BM_CD138pos (aliquot MMRF_2581_1_BM_CD138pos_T1_KHS5U_L12858) from MMRF case MMRF_2581, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,534 days).
Specimen MMRF_2581_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73c04f53-f566-4ecd-9c2f-529a1dd2eb64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2581_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2581_1_PB_Whole_C3_KHS5U_L12859; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d32dc92-3f14-49aa-9547-8803e7d363b2

The open-access MAF lists 129 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 27, Intron 17, Silent 17, 5'Flank 5, 3'Flank 5, Nonsense Mutation 4, 5'UTR 2, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 49/131 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ARHGAP22 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 88/168 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs755640836; called by muse, mutect2, varscan2
- CASR | c.2005G>A p.A669T (on ENST00000490131; = p.A746T on NM_000388.4) | Missense Mutation (SNP) | VAF 116/360 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs562364178, COSV56136669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREBZF | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 162/577 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758332106, COSV52630774; called by muse, mutect2, varscan2
- DHX9 | c.175A>G p.S59G | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs376667526; called by muse, mutect2, varscan2
- FAM189B | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.083); catalogued as rs149676360; called by muse, mutect2, varscan2
- FCRL5 | c.291C>G p.H97Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.018); catalogued as rs964243987; called by muse, mutect2, varscan2
- FREM2 | c.8200C>T p.R2734C | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs151140397; called by muse, mutect2, varscan2
- IGHV3-33 | c.162C>G p.H54Q | Missense Mutation (SNP) | VAF 133/165 reads (81%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.43); catalogued as rs375385478; called by muse, mutect2, varscan2
- IGLL5 | c.20A>G p.Q7R | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as rs1485151702; called by muse, mutect2, varscan2
- IGLV3-1 | c.63T>A p.Y21* | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | catalogued as rs368827772; called by muse, varscan2
- KALRN | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 123/224 reads (55%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs749891135, COSV53755839; called by muse, mutect2, varscan2
- LILRB3 | c.1911C>A p.Y637* (on ENST00000346401; = p.Y625* on NM_006864.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 122/478 reads (26%) | catalogued as COSV54429289; called by muse, mutect2, varscan2
- LRRC37A3 | c.4001G>A p.S1334N | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1361498435; called by muse, mutect2
- MYT1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 131/282 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1042416220; called by muse, mutect2, varscan2
- OR51F2 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309164019, COSV100438034, COSV59064918; called by muse, mutect2, varscan2
- OSBP2 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV100213725; called by muse, mutect2
- PDPR | c.2434G>A p.V812I | Missense Mutation (SNP) | VAF 128/424 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.251); catalogued as rs769864545; called by muse, mutect2, varscan2
- PTBP3 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs776684120; called by muse, mutect2, varscan2
- PTK2B | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57760705; called by muse, mutect2, varscan2
- SYNE1 | c.14116G>A p.V4706I (on ENST00000367255 / NM_182961.4; = p.V4635I on NM_033071.3) | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs374596074; called by muse, mutect2
- TBATA | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 121/270 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs374343305; called by muse, mutect2, varscan2
- VWA5B1 | c.3215C>T p.T1072M (on ENST00000375079; = p.T1067M on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs1394473481; called by muse, mutect2, varscan2
- ZFYVE28 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.528); catalogued as rs201929618; called by muse, mutect2, varscan2
- ADCY8 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- ANKIB1 | c.1771C>T p.R591* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- APOLD1 | c.181C>T p.R61W (on ENST00000326765 / NM_001130415.2; = p.R30W on NM_030817.3) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- ARSA | c.191del p.F64Sfs*16 | Frame Shift Del (DEL) | VAF 37/71 reads (52%) | called by mutect2, pindel, varscan2
- CEP126 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- DDX3X | c.620A>C p.K207T (on ENST00000399959; = p.K208T on NM_001356.5) | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKQ | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DOCK3 | c.5822A>C p.E1941A | Missense Mutation (SNP) | VAF 127/398 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DPP4 | c.1419C>T p.S473= | Splice Region (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- EPC2 | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 33/455 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); called by muse, mutect2
- FRMPD1 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 76/132 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIPK4 | c.350C>A p.T117N | Missense Mutation (SNP) | VAF 123/342 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); called by muse, varscan2
- IER5 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV2-70D | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, varscan2
- IGHV2-70D | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- IGHV2-70D | c.101C>G p.T34R | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, varscan2
- IGHV2-70D | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, varscan2
- ISLR2 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- KRT38 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LIME1 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- MX1 | c.762A>C p.K254N | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- NFRKB | c.2557A>T p.M853L (on ENST00000446488 / NM_001143835.2; = p.M878L on NM_006165.3) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OGT | c.1691A>G p.D564G | Missense Mutation (SNP) | VAF 92/122 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- RFTN1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 264/427 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, varscan2
- RGS17 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STARD9 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 96/186 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TBPL2 | c.520A>G p.N174D | Missense Mutation (SNP) | VAF 96/195 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM3 | c.6002A>G p.D2001G | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- VCPIP1 | c.302A>C p.N101T | Missense Mutation (SNP) | VAF 166/187 reads (89%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZFC3H1 | c.3985G>A p.D1329N | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ZNF407 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ADGRV1 | c.15910C>T p.L5304= | Silent (SNP) | VAF 81/289 reads (28%) | catalogued as rs764795815; called by muse, mutect2, varscan2
- CRPPA | c.1053C>T p.T351= (on ENST00000407010 / NM_001368197.1; = p.T301= on NM_001101417.4) | Silent (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- EIF2B2 | c.117A>G p.L39= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as rs755897515; called by muse, mutect2, varscan2
- IGHV1-69 | c.150C>T p.S50= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs11546800; called by mutect2, varscan2
- IGHV2-70 | c.102A>T p.T34= | Silent (SNP) | VAF 46/65 reads (71%) | catalogued as rs559222113; called by muse, varscan2
- IGHV2-70 | c.51C>G p.V17= | Silent (SNP) | VAF 36/52 reads (69%) | called by muse, varscan2
- LPAR5 | c.618G>A p.A206= | Silent (SNP) | VAF 51/112 reads (46%) | catalogued as COSV100321040, COSV61692092; called by muse, mutect2, varscan2
- NR3C1 | c.135A>G p.S45= | Silent (SNP) | VAF 83/310 reads (27%) | called by muse, mutect2, varscan2
- PARD6A | c.474G>A p.V158= | Silent (SNP) | VAF 106/299 reads (35%) | called by muse, mutect2, varscan2
- PEAK3 | c.874C>T p.L292= | Silent (SNP) | VAF 95/274 reads (35%) | called by muse, mutect2, varscan2
- PLCB2 | c.1218G>A p.S406= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as rs61755437; called by muse, mutect2, varscan2
- RFTN1 | c.489T>C p.P163= | Silent (SNP) | VAF 98/159 reads (62%) | called by muse, varscan2
- SCNN1B | c.1197C>T p.C399= | Silent (SNP) | VAF 204/446 reads (46%) | called by muse, mutect2, varscan2
- SRSF5 | c.684T>C p.R228= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as rs374231301; called by muse, mutect2, varscan2
- STARD9 | c.1881G>T p.A627= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, varscan2
- ZNF408 | c.210A>G p.E70= | Silent (SNP) | VAF 41/175 reads (23%) | called by muse, mutect2, varscan2
- ZNF567 | c.1443C>T p.H481= (on ENST00000536254 / NM_001322913.1; = p.H450= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 76/272 reads (28%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021147 G>C | 5'Flank (SNP) | VAF 84/202 reads (42%) | called by muse, mutect2, varscan2
- BMP6 | c.*1152_*1175del | 3'UTR (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- C6orf136 | c.72+261C>G | Intron (SNP) | VAF 48/145 reads (33%) | catalogued as COSV99528253; called by muse, mutect2, varscan2
- CBLB | c.2202-54C>T | Intron (SNP) | VAF 113/190 reads (59%) | called by muse, mutect2, varscan2
- CCDC187 | c.*2841C>T | 3'UTR (SNP) | VAF 66/212 reads (31%) | called by muse, mutect2, varscan2
- CDH19 | c.*1668G>A | 3'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- CIBAR1 | c.433-745G>A | Intron (SNP) | VAF 120/132 reads (91%) | called by muse, mutect2, varscan2
- COA1 | c.-38-649G>A | Intron (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- CUL3 | c.*545A>G | 3'UTR (SNP) | VAF 46/96 reads (48%) | catalogued as rs886055693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCLRE1A | c.-888G>A | 5'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- DNAJA4 | c.-7-71A>G | Intron (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- DNAJC4 | c.614+36T>C | Intron (SNP) | VAF 342/551 reads (62%) | called by muse, mutect2, varscan2
- DUSP8 | c.*749T>C | 3'UTR (SNP) | VAF 89/154 reads (58%) | called by muse, mutect2, varscan2
- GABRP | c.*1347G>T | 3'UTR (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- GCSAM | chr3:112135049 A>C | 5'Flank (SNP) | VAF 121/182 reads (66%) | called by muse, mutect2, varscan2
- GRM4 | c.873-199G>A | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as rs10214848; called by muse, varscan2
- HLCS | chr21:36749527 G>A | 3'Flank (SNP) | VAF 40/109 reads (37%) | called by muse, mutect2, varscan2
- HOXB4 | c.*1082C>T | 3'UTR (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863418 A>G | 5'Flank (SNP) | VAF 9/24 reads (38%) | catalogued as rs1174739229; called by muse, varscan2
- IGHJ6 | chr14:105863423 T>C | 5'Flank (SNP) | VAF 12/21 reads (57%) | catalogued as rs937738884; called by muse, varscan2
- IGKV1-33 | c.-20A>G | 5'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- IKZF3 | c.*2575T>G | 3'UTR (SNP) | VAF 45/118 reads (38%) | called by muse, mutect2, varscan2
- ITIH5 | c.*3598C>G | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- IZUMO3 | c.*170A>C | 3'UTR (SNP) | VAF 140/245 reads (57%) | called by muse, mutect2, varscan2
- KCTD21 | c.*161A>G | 3'UTR (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- KIF2A | c.160-88G>C | Intron (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2
- KLHL6 | c.1350+116G>T | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- METAP2 | chr12:95474080 T>C | 5'Flank (SNP) | VAF 76/195 reads (39%) | catalogued as rs976381423; called by muse, mutect2, varscan2
- MUTYH | c.779+34del | Intron (DEL) | VAF 75/214 reads (35%) | called by mutect2, pindel, varscan2
- NCR3LG1 | c.*4681dup | 3'UTR (INS) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- NOL9 | c.*3175A>G | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- NOX4 | c.*1685G>C | 3'UTR (SNP) | VAF 119/237 reads (50%) | called by muse, mutect2, varscan2
- NPTXR | c.*1391A>C | 3'UTR (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- NTPCR | c.505-836T>C | Intron (SNP) | VAF 100/241 reads (41%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | chr9:110172437 A>T | 3'Flank (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- PANK3 | c.*3209G>A | 3'UTR (SNP) | VAF 23/84 reads (27%) | catalogued as rs1026590761; called by muse, mutect2, varscan2
- PCDHGA12 | c.*418C>T | 3'UTR (SNP) | VAF 127/239 reads (53%) | called by muse, mutect2, varscan2
- PLEKHG3 | chr14:64749155 C>T | 3'Flank (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- POGZ | c.*1589G>A | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- PTPRZ1 | c.5167-74C>T | Intron (SNP) | VAF 25/62 reads (40%) | catalogued as rs1322575048; called by muse, mutect2
- RAB27B | c.*4166G>A | 3'UTR (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- RELA | c.186+51T>G | Intron (SNP) | VAF 65/234 reads (28%) | called by muse, mutect2, varscan2
- SEC14L3 | c.*520C>T | 3'UTR (SNP) | VAF 23/167 reads (14%) | catalogued as rs563172302; called by muse, mutect2, varscan2
- SEMA3A | c.*2213T>A | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- SLC5A12 | c.*652C>G | 3'UTR (SNP) | VAF 73/138 reads (53%) | called by muse, mutect2, varscan2
- SMTN | c.-80-575G>A | Intron (SNP) | VAF 4/48 reads (8%) | catalogued as rs932268267; called by muse, mutect2
- SPATA8 | n.426T>C | RNA (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- SRPRA | c.1788+32T>C | Intron (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- TBC1D2B | c.*2025C>T | 3'UTR (SNP) | VAF 105/460 reads (23%) | catalogued as rs564163671; called by muse, varscan2
- TMEM144 | c.*917T>G | 3'UTR (SNP) | VAF 9/23 reads (39%) | catalogued as rs376414090; called by muse, varscan2
- TMPRSS11A | chr4:67910196 del ATAACAAA | 3'Flank (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- TTC9 | c.*1746G>T | 3'UTR (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- TTL | c.*1827A>G | 3'UTR (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- UBE2D3 | c.-336-252T>C | Intron (SNP) | VAF 157/183 reads (86%) | called by muse, mutect2, varscan2
- UTS2B | chr3:191265517 A>C | 3'Flank (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- VMP1 | c.1077+63G>A | Intron (SNP) | VAF 85/202 reads (42%) | called by muse, mutect2, varscan2
- ZNF587 | c.*1414C>T | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
